Somatic mutation profile of tumor specimen ALCH-B2S8-TTP1-A (aliquot ALCH-B2S8-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2S8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.0 years (24,458 days).
Specimen ALCH-B2S8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4984fa7a-7b76-401d-b188-cba2219d81b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2S8-NB1-A (Blood Derived Normal), aliquot ALCH-B2S8-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4834cacf-ae4c-44fa-9741-19542aaffd1b

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Nonsense Mutation 9, Intron 6, RNA 3, In Frame Del 2, 3'UTR 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375593105; called by muse, mutect2
- ANKRD31 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs971055487, COSV57165694; called by muse, mutect2
- ATP7B | c.3578C>T p.A1193V | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1469278742, CD118185; called by muse, mutect2
- C22orf23 | c.361_363del p.K121del | In Frame Del (DEL) | VAF 4/35 reads (11%) | catalogued as rs754613776; called by mutect2, pindel
- CYP2C8 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752621676, COSV100987990; called by muse, mutect2
- DENND2C | c.1787G>A p.R596H (on ENST00000393274 / NM_001256404.2; = p.R539H on NM_198459.4) | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as rs371838270; called by muse, mutect2
- DHRS1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV55385634; called by mutect2, varscan2
- FERD3L | c.399C>G p.Y133* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV51762499, COSV51764707; called by muse, mutect2, varscan2
- FLT1 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV56725445; called by muse, mutect2
- FLT4 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757396801, COSV56098351, COSV56126835; called by muse, mutect2, varscan2
- GRIN1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1332508025, COSV100159974; called by muse, mutect2
- JARID2 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs920736659; called by muse, mutect2, varscan2
- KRT2 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs747178935, COSV59011400; called by muse, mutect2, varscan2
- LRP1B | c.2802C>A p.C934* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as rs138953199; called by muse, mutect2
- PNLIP | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 11/152 reads (7%) | catalogued as COSV65040522; called by muse, mutect2
- SLC26A3 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs776888978, COSV60639399; called by muse, mutect2
- SOCS7 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1208396924; called by muse, mutect2
- TFR2 | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1489134774, COSV56156829; called by muse, mutect2
- TMEM117 | c.931G>C p.V311L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56900727; called by muse, varscan2
- TRIM64C | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1195063554, COSV73267311; called by muse, mutect2
- UNC79 | c.5803G>C p.A1935P (on ENST00000393151 / NM_001346218.2; = p.A1758P on NM_020818.5) | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV56416742; called by muse, mutect2
- AHCTF1 | c.1065A>T p.L355F (on ENST00000366508; = p.L329F on NM_015446.5) | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ARHGEF17 | c.1558A>G p.I520V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D3 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- CALCR | c.766G>T p.E256* (on ENST00000649521 / NM_001164737.2; = p.E240* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- CCDC141 | c.3891G>T p.E1297D | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2
- CDH7 | c.719del p.G240Efs*11 | Frame Shift Del (DEL) | VAF 24/163 reads (15%) | called by mutect2, pindel, varscan2
- CEP120 | c.1101A>T p.L367F | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2
- CRTC3 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- CTHRC1 | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FAM71E2 | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- FAM83B | c.2155G>T p.E719* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- IGLV11-55 | c.201A>C p.L67F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by mutect2, varscan2
- JARID2 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- LAMB1 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- LCE1A | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); called by muse, mutect2
- LPIN2 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP2 | c.1468A>T p.T490S | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2
- MPDZ | c.2076del p.M693Cfs*9 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- NEUROD6 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- NUDT22 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NWD1 | c.3978C>A p.D1326E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.32); called by muse, mutect2
- NYX | c.1026C>A p.C342* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- OBSCN | c.19820A>G p.D6607G | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10D3 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR11H2 | c.7G>T p.V3F (on ENST00000556246; = p.V14F on NM_001197287.1) | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAFAH2 | c.492_503del p.E164_F168delinsD | In Frame Del (DEL) | VAF 19/150 reads (13%) | called by mutect2, pindel
- POT1 | c.1508G>T p.C503F | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- POT1 | c.221A>T p.K74I | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- POTEF | c.1167G>T p.R389S | Missense Mutation (SNP) | VAF 31/506 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); called by muse, mutect2
- PSMA2 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RACGAP1 | c.1726G>C p.G576R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- RAD21L1 | c.649A>G p.N217D | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIT2 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- SPOCK1 | c.410A>T p.K137M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- SRSF11 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- THBS4 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- TMPO | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- TNN | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRHR | c.974A>T p.Q325L | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TSFM | c.805A>G p.N269D (on ENST00000323833 / NM_001172696.2; = p.N248D on NM_005726.6) | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- TTC3 | c.3973A>T p.R1325* | Nonsense Mutation (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- UGGT2 | c.2061G>T p.L687F | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- USP29 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.196); called by muse, varscan2
- VWDE | c.3367G>T p.E1123* | Nonsense Mutation (SNP) | VAF 30/259 reads (12%) | called by muse, mutect2, varscan2
- WDR7 | c.3199A>T p.T1067S | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF534 | c.1542G>T p.K514N (on ENST00000332323 / NM_001143939.3; = p.K501N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF701 | c.1281G>T p.K427N (on ENST00000301093; = p.K361N on NM_018260.3) | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- ZSCAN25 | c.1181A>G p.Q394R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- AL121899.2 | c.1242C>A p.A414= | Silent (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- ARFGEF3 | c.2283G>T p.A761= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- DSG3 | c.156G>C p.V52= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as COSV57129547; called by muse, mutect2
- FAT3 | c.13317T>A p.P4439= | Silent (SNP) | VAF 11/147 reads (7%) | called by muse, mutect2
- FIGLA | c.444G>A p.S148= | Silent (SNP) | VAF 12/283 reads (4%) | catalogued as rs370759819; called by muse, mutect2
- HEPH | c.1563C>A p.V521= (on ENST00000343002; = p.V254= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV100294364, COSV57958868; called by muse, mutect2, varscan2
- MIA2 | c.1920C>G p.L640= | Silent (SNP) | VAF 16/219 reads (7%) | catalogued as COSV54492043; called by muse, mutect2
- MITF | c.399C>T p.A133= (on ENST00000448226 / NM_006722.3; = p.A27= on NM_000248.4) | Silent (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- NELL1 | c.297T>C p.T99= | Silent (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- NPAP1 | c.894C>A p.S298= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV61510828; called by mutect2, varscan2
- NPR1 | c.240G>T p.T80= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PTH2R | c.1362C>A p.T454= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- RNF225 | c.234C>T p.P78= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- SPAM1 | c.246C>T p.N82= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1431798930, COSV99773193; called by muse, mutect2, varscan2
- ZBED6 | c.2217C>G p.L739= | Silent (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- ZNF532 | c.1983C>G p.L661= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- AC091163.2 | n.517A>T | RNA (SNP) | VAF 14/127 reads (11%) | catalogued as rs770035650; called by muse, mutect2, varscan2
- AC243919.1 | n.415+27C>T | Intron (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- CLU | c.*1014T>C | 3'UTR (SNP) | VAF 49/381 reads (13%) | called by muse, mutect2, varscan2
- DLX1 | c.514-483C>T | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- EYA4 | c.*40G>T | 3'UTR (SNP) | VAF 30/223 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.1767-7283T>A | Intron (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2
- FAM183BP | n.833C>T | RNA (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- LEMD2 | c.931-11_931-10insGG | Intron (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- MTRNR2L6 | chr7:142671089 C>A | 3'Flank (SNP) | VAF 24/271 reads (9%) | called by muse, mutect2
- PCDHGA3 | c.2425-66906G>T | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- UGT2B27P | n.827A>C | RNA (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- ZNF528 | c.272-828G>T | Intron (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
